Gene-level copy-number profile of tumor specimen TCGA-06-0743-01A from TCGA case TCGA-06-0743, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.6 years (25,434 days).
Specimen TCGA-06-0743-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.a98b56fc-4d6c-434c-a57b-3d9d2f140851.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0743-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/746d5710-e6d9-4db0-8639-89ad3a36a384

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 96; copy number 1: 5,540; copy number 2: 39,256; copy number 3: 11,506; copy number 4: 3,134; copy number 5: 136; copy number 21: 111; copy number 27: 41.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0743-01A-01D-0333-01): tumor purity 0.85, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,705,338–26,118,408, 96 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 288 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:53,377,641–63,529,761, 136 genes, copy number 5 (broad region; genes not listed).
- chr7:54,576,052–62,275,678, 152 genes, copy number 21–27 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,160. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
